Gene-level copy-number profile of tumor specimen C3N-01755-01 from CPTAC case C3N-01755, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.1 years (24,868 days).
Specimen C3N-01755-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a49e5023-b8b2-4d3c-9ee6-538425f925cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01755-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/cedfa164-4321-47cb-bee2-2b69069c3833

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 700; copy number 2: 12,323; copy number 3: 14,200; copy number 4: 17,517; copy number 5: 7,451; copy number 6: 3,729; copy number 7: 446; copy number 8: 2,292; copy number 11: 29; copy number 12: 14; copy number 15: 118; copy number 22: 43; copy number 25: 4; copy number 38: 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:129,397,062–129,461,076, 2 genes (within-gene range 0–4): MIR4460, ADAMTS19-AS1.
- chr9:42,011,350–42,011,610, 1 gene (within-gene range 0–2): RN7SL343P.
- chr9:43,109,866–60,964,196, 8 genes: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr14:42,259,731–42,268,586, 1 gene: AL445074.1.
- chr14:102,592,649–102,933,596, 7 genes (within-gene range 0–2): RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN.
- chr14:102,933,574–102,937,177, 1 gene (within-gene range 0–2): AL117209.1.
- chr15:19,878,555–19,988,117, 8 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7.
- chr15:20,005,905–20,014,208, 4 genes: IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr16:32,439,069–32,441,159, 1 gene: PABPC1P13.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–3): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 209 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,271,302–42,555,195, 9 genes, copy number 22–38: IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr9:42,921,443–43,045,120, 6 genes, copy number 12: CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr9:61,190,003–61,582,675, 8 genes, copy number 12: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:63,581,254–64,463,196, 19 genes, copy number 11: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2.
- chr11:69,072,915–69,162,440, 1 gene, copy number 25 (within-gene range 4–25): AP003071.5.
- chr11:69,103,493–74,009,085, 166 genes, copy number 11–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
